CCDI case PBCSKL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e717d8b3-b546-48f6-ba9d-5af5dffdaf08

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.2 years (2,643 days).

Biospecimens (3 samples)
- Sample 0DYM1F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYM1X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYM2A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
